Somatic mutation profile of tumor specimen 0DNUGT from CCDI case PBCBZY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.5 years (166 days).
Specimen 0DNUGT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1783ded7-0a63-477d-8841-0d9fc5897837.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNUGB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d2f1796-cbe7-4eb7-9d8f-5b4325ba6db1

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR5M8 | c.15C>T p.C5= | Silent (SNP) | VAF 186/478 reads (39%) | catalogued as rs1486961971; called by muse, mutect2, varscan2
